Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3376, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3376-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN INFORMATION

Collected:

Accession

Received:

Acct / Reg

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left kidney, radical nephrectomy:
Renal carcinoma.

Tumor Characteristics:

1. Histologic type: Clear cell adenocarcinoma
2. Tumor site: Upper pole.
3. Tumor size: Up to 2.5 cm maximal diameter.
4. Macroscopic extent of tumor: Limited to kidney.
5. Nuclear grade: Fuhrman grade: 2/4.
6. Lymphovascular space invasion: Not identified.
7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Venacava invasion: Not resected.
10. Adrenal gland: Present, negative for tumor.

Surgical Margin Status:

1. Soft tissue margins: Negative for tumor.
2. Ureteral margin: Negative for tumor.
3. Vascular Margin: Negative for tumor.

Lymph Node Status:

1. No lymph nodes identified.

Other Significant Findings:

1. The background non-neoplastic kidney shows pronounced arterial and arteriolonephrosclerosis as well as nodular glomerulosclerosis. Multiple specimens stains will be performed to further evaluate these changes, with an addendum report to follow.
2. pTNM stage: T1N0MX.

Staging sheet

Electronic Signature:

COMMENTS:

has reviewed the case and concurs with the diagnosis.

CLINICAL INFORMATION

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: CA left kidney.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in a single container labeled with the patient's name, [REDACTED]. The specimen consists of a kidney with attached perinephric fat measuring 20.0 x 10.0 x 5.5 cm, weighing 463 gm. There is an attached adrenal gland that measures 3.0 x 1.0 x 1.0 cm. The cut surface is golden yellow and shows a well demarcated cortex and medulla. There are no lesions identified. The soft tissue margin has been inked. The ureter stump is identified, measuring 6.0 cm in length and 0.3 cm in diameter. The surface is gray to pink-tan. On sectioning the ureter the mucosal surface is yellow to gray-tan and smooth. There are no lesions seen grossly. The renal artery stump measures 0.7 cm in length and 0.5 cm in diameter, is slightly atherosclerotic but grossly unremarkable. The renal vein stump measures 0.7 cm in length and up to 1.0 cm in diameter and is grossly unremarkable. The kidney is bisected and reveals a circumscribed, golden yellow mass within the upper pole that measures 2.5 x 2.5 x 0.5 cm. The mass is confined to the capsule with no invasion into the surrounding perinephric fat. The renal pelvis and calices are gray-tan, smooth, and are uninvolved by the mass. There are multiple small, brown-tan calculi noted within the calices. There are no other lesions identified. The surrounding renal cortex is brown-tan and measures 0.5 cm in greatest dimension and displays a well demarcated cortex and renal pyramids. Received with the specimen are two cassettes, one green and one yellow, labeled [REDACTED]. Representative sections are submitted in cassettes [REDACTED] as follows: Sections from mass in blocks 1 through 4; sections from surrounding uninvolved renal cortex in block 5; ureter block 6; renal artery and vein block 7; adrenal block 8.

Source: NCI Genomic Data Commons file 2ee9815b-660f-4b74-80cc-f0b8e6a1cb9d (TCGA-A3-3376.4C1CDB16-95E9-487A-AF2A-55E73FA5ED13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).